CCDI case PBCNTM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined sites in lip, oral cavity and pharynx.
https://portal.gdc.cancer.gov/cases/44c83211-5d0e-4a0a-9a33-ea78d41c9d62

Demographics
Sex at birth: male; Race: american indian or alaska native.

Diagnoses (1)
1. Craniopharyngioma, adamantinomatous: ICD-O-3 morphology code: 9351/1; Tissue or organ of origin: Craniopharyngeal duct; Age at diagnosis: 13.2 years (4,837 days).

Biospecimens (3 samples)
- Sample 0DWYUM: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWYV6: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWYWH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
